Somatic mutation profile of tumor specimen BA2097D (aliquot aq-BA2097D) from BEATAML1.0 case 2201, project BEATAML1.0-COHORT (Functional Genomic Landscape of Acute Myeloid Leukemia). Sex at birth: male; Vital status: Alive; Primary diagnosis: Acute myeloid leukemia with myelodysplasia-related changes; Tissue or organ of origin: Bone marrow; Age at diagnosis: 77.3 years (28,221 days).
Specimen BA2097D: Sample type: Recurrent Blood Derived Cancer - Peripheral Blood; Tissue type: Tumor; Tumor descriptor: Recurrence; Specimen type: Peripheral Blood NOS; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 4764f182-ed37-4d1c-856c-c67383bf967a.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen BA2128D (Solid Tissue Normal), aliquot aq-BA2128D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/be1fa221-d4a3-40a9-80c1-f317900acc30

The open-access MAF lists 5 somatic variants for this specimen: 3 protein-altering or splice-affecting, 1 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 2, Intron 1, Splice Site 1, Silent 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PIGO | c.2857G>T p.G953C | Missense Mutation (SNP) | VAF 3/33 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV53053666; called by muse, mutect2
- KMT5B | c.654-1G>A p.X218_splice | Splice Site (SNP) | VAF 19/66 reads (29%) | called by muse, mutect2, varscan2
- OR52E2 | c.751G>T p.A251S | Missense Mutation (SNP) | VAF 3/20 reads (15%) | SIFT tolerated (0.07); PolyPhen benign (0.168); called by muse, mutect2
- MPP5 | c.669C>A p.A223= | Silent (SNP) | VAF 8/75 reads (11%) | called by muse, mutect2
- IGFN1 | c.1241+2661G>A | Intron (SNP) | VAF 9/66 reads (14%) | catalogued as COSV55171371; called by muse, mutect2, varscan2
